Gene-level copy-number profile of tumor specimen TARGET-40-PARDAX-01A from TARGET case TARGET-40-PARDAX, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.1 years (3,680 days).
Specimen TARGET-40-PARDAX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.366c488a-cfe1-5b31-b34a-50d1eb75756e.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PARDAX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 383 have no estimate.
https://portal.gdc.cancer.gov/files/ae2c0e9d-a961-4a24-a483-ba31aea7518c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 386; copy number 1: 29,131; copy number 2: 27,225; copy number 3: 3,152; copy number 4: 247; copy number 5: 91; copy number 7: 5; copy number 8: 3.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–846,561, 11 genes (within-gene range 0–1): LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32.
- chr8:7,082,971–7,187,316, 6 genes: AF238378.1, AF228730.5, AF228730.2, RPS3AP30, SNRPCP6, SNRPCP15.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr17:46,193,576–46,196,723, 1 gene: KANSL1-AS1.
- chr20:14,884,250–14,935,363, 2 genes: MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 99 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:135,234,131–137,092,183, 8 genes, copy number 7–8 (within-gene range 3–8): LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1.
- chr18:67,940,949–75,074,205, 83 genes, copy number 5 (broad region; genes not listed).
- chr18:80,034,346–80,097,088, 1 gene, copy number 5 (within-gene range 4–5): AC090360.1.
- chr18:80,046,900–80,247,514, 7 genes, copy number 5 (within-gene range 4–5): RBFADN, SLC25A6P4, ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Autosomal genes at a single copy (total copy number 1): 26,744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
